Somatic mutation profile of tumor specimen MP2PRT-PASKFJ-TMP1-A (aliquot MP2PRT-PASKFJ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASKFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,490 days).
Specimen MP2PRT-PASKFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5cd4054-5ed2-45ad-af6b-f6e104f9e8b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKFJ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84ee0dd1-8dab-47e3-bfaa-ffb5540a320f

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 138/333 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 259/773 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- DPYSL4 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 208/769 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs747431205, COSV58309269; called by muse, mutect2, varscan2
- ELFN1 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 211/452 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1444533304, COSV70034431; called by muse, mutect2, varscan2
- GC | c.831+1G>A p.X277_splice | Splice Site (SNP) | VAF 97/294 reads (33%) | catalogued as rs113964594; called by muse, mutect2, varscan2
- HCN4 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420807618, COSV56082015; called by muse, mutect2, varscan2
- OR51E2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 179/443 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs771709241, COSV67809108; called by muse, mutect2, varscan2
- PLCL1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771861039; called by muse, mutect2, varscan2
- WDR17 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 139/489 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762164967, COSV54572833; called by muse, mutect2, varscan2
- FOXI2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 251/884 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRPS27 | c.360T>A p.D120E | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SALL1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 173/428 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKS1B | c.2847C>T p.D949= (on ENST00000547776 / NM_152788.4; = p.D175= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 157/399 reads (39%) | catalogued as rs768426718, COSV100227281; called by muse, mutect2, varscan2
- ATIC | c.1473C>T p.I491= | Silent (SNP) | VAF 109/278 reads (39%) | catalogued as rs775720376, COSV52692767; called by muse, mutect2, varscan2
- IGFL2 | c.52T>C p.L18= (on ENST00000377693 / NM_001135113.2; = p.L29= on NM_001002915.2) | Silent (SNP) | VAF 155/363 reads (43%) | called by muse, mutect2, varscan2
- LRRC27 | c.648C>T p.N216= | Silent (SNP) | VAF 182/688 reads (26%) | catalogued as rs769922074; called by muse, mutect2, varscan2
- POU6F1 | c.1683C>A p.A561= | Silent (SNP) | VAF 203/443 reads (46%) | catalogued as COSV61328043; called by muse, mutect2, varscan2
- TOX3 | c.468C>T p.S156= | Silent (SNP) | VAF 185/461 reads (40%) | catalogued as COSV54866277; called by muse, mutect2, varscan2
- USH2A | c.6435C>T p.H2145= | Silent (SNP) | VAF 191/451 reads (42%) | catalogued as rs754125117; called by muse, mutect2, varscan2
